Gene-level copy-number profile of tumor specimen TCGA-HZ-7922-01A from TCGA case TCGA-HZ-7922, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 61.4 years (22,413 days).
Specimen TCGA-HZ-7922-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.a4972b23-c8e9-4574-909b-9a35d87ecf6a.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HZ-7922-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 351 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4c4863dd-f88b-4376-9688-13b932cfc086

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 626; copy number 1: 634; copy number 2: 22,211; copy number 3: 24,406; copy number 4: 10,444; copy number 5: 275; copy number 6: 1,457; copy number 7: 17; copy number 9: 120; copy number 11: 82.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HZ-7922-01A-11D-2153-01): tumor purity 0.38, ploidy 2.95, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 74 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:186,890,969–186,892,983, 2 genes: AC108865.1, AC108865.2.
- chr5:82,968,888–83,077,863, 5 genes: ST13P12, AC027338.1, AC104118.1, TMEM167A, SCARNA18.
- chr6:127,118,671–127,199,481, 1 gene (within-gene range 0–2): RSPO3.
- chr9:20,658,309–23,438,700, 64 genes (within-gene range 0–2) (broad region; genes not listed).
- chr19:1,905,372–1,926,013, 2 genes (within-gene range 0–2): SCAMP4, ADAT3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 219 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene, copy number 9: CFHR3.
- chr8:92,420,850–93,700,433, 17 genes, copy number 7 (within-gene range 6–7): AC022695.3, AC091096.1, AC104211.1, AC104211.3, FLJ46284, AC104211.2, AC117834.2, AC117834.1, TRIQK, IRF5P1, MIR8084, C8orf87, LINC00535, AC016885.1, AC016885.3, AC016885.2, RNA5SP274.
- chr14:18,333,726–19,936,757, 82 genes, copy number 11 (broad region; genes not listed).
- chr14:105,546,610–106,377,733, 119 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 634. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
